Somatic mutation profile of cancer-model specimen HCM-BROD-0703-C16-85M (3D Organoid, passage 6; aliquot HCM-BROD-0703-C16-85M-01D-A85K-36), derived from the metastatic tumor of HCMI case HCM-BROD-0703-C16, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 53.3 years (19,452 days).
Specimen HCM-BROD-0703-C16-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 6.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9100d240-6b74-42e7-b1a0-ad40268e0e2a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0703-C16-10A (Blood Derived Normal), aliquot HCM-BROD-0703-C16-10A-01D-A85K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/98aed1d5-c69f-42fb-a9ad-10a8e618f47c

The open-access MAF lists 210 somatic variants for this specimen: 158 protein-altering or splice-affecting, 45 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 142, Silent 45, Nonsense Mutation 5, Frame Shift Ins 4, Frame Shift Del 3, Intron 3, In Frame Del 2, Splice Region 2, 5'UTR 1, 3'UTR 1, 3'Flank 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RHOA | c.125A>G p.Y42C | Missense Mutation (SNP) | VAF 442/443 reads (100%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as rs1057519954, COSV69041523, COSV69041892, COSV69042190; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 387/388 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABR | c.1649A>G p.K550R (on ENST00000302538 / NM_021962.5; = p.K513R on NM_001092.5) | Missense Mutation (SNP) | VAF 51/467 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.143); catalogued as rs1234928649; called by muse, mutect2, varscan2
- AC127029.3 | c.364A>G p.T122A | Missense Mutation (SNP) | VAF 99/641 reads (15%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV100033278; called by muse, mutect2, varscan2
- ADD2 | c.1151G>A p.R384H | Missense Mutation (SNP) | VAF 130/471 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as rs782644174, COSV52455124; called by muse, mutect2, varscan2
- AGO2 | c.2126A>C p.K709T | Missense Mutation (SNP) | VAF 18/427 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55048629; called by muse, mutect2
- AOAH | c.128G>T p.G43V | Missense Mutation (SNP) | VAF 151/342 reads (44%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.684); catalogued as COSV99333481; called by muse, mutect2, varscan2
- APBA3 | c.1556G>A p.G519D | Missense Mutation (SNP) | VAF 170/362 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs889901254; called by muse, mutect2, varscan2
- ARID1A | c.2971dup p.T991Nfs*16 | Frame Shift Ins (INS) | VAF 84/316 reads (27%) | catalogued as COSV100253960; called by mutect2, pindel, varscan2
- ARID1B | c.5962G>T p.E1988* | Nonsense Mutation (SNP) | VAF 584/585 reads (100%) | catalogued as rs1554237818, COSV51672885; called by muse, mutect2, varscan2
- BMPER | c.917A>G p.K306R | Missense Mutation (SNP) | VAF 30/231 reads (13%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.574); catalogued as rs759924865; called by muse, varscan2
- CCDC136 | c.1577C>T p.P526L | Missense Mutation (SNP) | VAF 115/422 reads (27%) | SIFT tolerated (0.38); PolyPhen benign (0.01); catalogued as rs1372831000; called by muse, mutect2, varscan2
- CHST3 | c.832C>T p.R278W | Missense Mutation (SNP) | VAF 54/686 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs1342834475; called by muse, mutect2
- COL14A1 | c.4471C>T p.R1491W | Missense Mutation (SNP) | VAF 109/363 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs746241584, COSV52862683; called by muse, mutect2, varscan2
- COX16 | c.104A>G p.E35G | Missense Mutation (SNP) | VAF 40/370 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1022200674; called by muse, mutect2, varscan2
- DLX5 | c.540+8C>T | Splice Region (SNP) | VAF 228/836 reads (27%) | catalogued as rs775634016; called by muse, mutect2, varscan2
- DNAH10 | c.2221T>G p.L741V (on ENST00000409039; = p.L680V on NM_207437.3) | Missense Mutation (SNP) | VAF 179/490 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as rs373509532; called by muse, mutect2, varscan2
- EP400 | c.6821C>T p.A2274V | Missense Mutation (SNP) | VAF 86/318 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs539306836; called by muse, mutect2, varscan2
- FAM78B | c.575G>A p.R192K | Missense Mutation (SNP) | VAF 148/473 reads (31%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.953); catalogued as COSV100597297; called by muse, mutect2, varscan2
- FBF1 | c.2906G>A p.R969H (on ENST00000586717; = p.R984H on NM_001319193.1) | Missense Mutation (SNP) | VAF 534/759 reads (70%) | SIFT tolerated (0.2); PolyPhen benign (0.205); catalogued as rs1221486992; called by muse, mutect2, varscan2
- FBXO31 | c.1121G>A p.R374H | Missense Mutation (SNP) | VAF 505/745 reads (68%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs1174331035, COSV61150241; called by muse, mutect2, varscan2
- GCNT3 | c.847_849del p.K283del | In Frame Del (DEL) | VAF 135/608 reads (22%) | catalogued as rs777839068; called by pindel, varscan2
- GPKOW | c.892G>A p.D298N | Missense Mutation (SNP) | VAF 150/150 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as COSV50243076; called by muse, mutect2, varscan2
- HEMGN | c.322del p.T108Lfs*7 | Frame Shift Del (DEL) | VAF 58/393 reads (15%) | catalogued as rs751768399; called by mutect2, pindel, varscan2
- IL17B | c.489C>A p.C163* | Nonsense Mutation (SNP) | VAF 250/513 reads (49%) | catalogued as rs1191306380; called by muse, mutect2, varscan2
- INTS1 | c.784C>T p.P262S | Missense Mutation (SNP) | VAF 326/621 reads (52%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.712); catalogued as COSV67179798; called by muse, varscan2
- INTS2 | c.2419C>G p.R807G | Missense Mutation (SNP) | VAF 110/464 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs777097380; called by muse, mutect2, varscan2
- KCNB2 | c.2426C>A p.T809N | Missense Mutation (SNP) | VAF 26/564 reads (5%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.649); catalogued as rs1355800336; called by muse, mutect2
- KCNK7 | c.626C>T p.S209L | Missense Mutation (SNP) | VAF 512/513 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1484589261; called by muse, mutect2, varscan2
- MYEF2 | c.1343del p.G448Dfs*8 | Frame Shift Del (DEL) | VAF 44/234 reads (19%) | catalogued as COSV51047294; called by mutect2, pindel, varscan2
- MYO1E | c.2656T>C p.W886R | Missense Mutation (SNP) | VAF 33/533 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs749509539; called by muse, mutect2
- NALCN | c.2006G>A p.R669H | Missense Mutation (SNP) | VAF 116/116 reads (100%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.607); catalogued as rs1270231284, COSV51916991; called by muse, mutect2, varscan2
- NAPSA | c.1199G>A p.R400H | Missense Mutation (SNP) | VAF 179/896 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs1303590192, COSV99515738; called by muse, mutect2, varscan2
- OR5D18 | c.89T>C p.L30P | Missense Mutation (SNP) | VAF 176/533 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs1353426770; called by muse, mutect2, varscan2
- OR8G1 | c.545T>G p.L182R | Missense Mutation (SNP) | VAF 135/395 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.106); catalogued as COSV100422176, COSV58381567; called by muse, mutect2, varscan2
- PKHD1L1 | c.5677G>A p.D1893N | Missense Mutation (SNP) | VAF 124/438 reads (28%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as COSV65743144; called by muse, mutect2, varscan2
- PTCH2 | c.425C>A p.A142D | Missense Mutation (SNP) | VAF 131/401 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV64713510; called by muse, mutect2, varscan2
- PTPRN2 | c.1181G>A p.R394H | Missense Mutation (SNP) | VAF 49/328 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs17847427, COSV67057255; called by muse, mutect2, varscan2
- RHD | c.1010T>A p.L337Q | Missense Mutation (SNP) | VAF 84/463 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM151435; called by muse, mutect2, varscan2
- SART3 | c.1264G>A p.E422K (on ENST00000228284; = p.E404K on NM_014706.4) | Missense Mutation (SNP) | VAF 95/270 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as rs759410185, COSV99934165; called by muse, mutect2, varscan2
- SDK1 | c.3140C>A p.A1047D | Missense Mutation (SNP) | VAF 56/433 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV67380986; called by muse, mutect2, varscan2
- SLC12A1 | c.2805dup p.W936Mfs*5 | Frame Shift Ins (INS) | VAF 82/166 reads (49%) | catalogued as rs776749406; called by mutect2, varscan2
- SLC23A2 | c.55A>G p.T19A | Missense Mutation (SNP) | VAF 43/406 reads (11%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.026); catalogued as rs1197082437; called by muse, mutect2, varscan2
- SNTG1 | c.650C>G p.S217C | Missense Mutation (SNP) | VAF 124/517 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV99381691; called by muse, mutect2, varscan2
- SORCS3 | c.1406T>G p.I469S | Missense Mutation (SNP) | VAF 137/288 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.254); catalogued as COSV63801960, COSV63810858; called by muse, mutect2, varscan2
- SUPT7L | c.575A>G p.K192R | Missense Mutation (SNP) | VAF 81/579 reads (14%) | SIFT tolerated (0.7); PolyPhen benign (0.011); catalogued as COSV61822297; called by muse, mutect2, varscan2
- TLN2 | c.704A>G p.E235G | Missense Mutation (SNP) | VAF 74/740 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.09); catalogued as rs1357993741; called by muse, mutect2, varscan2
- TSC2 | c.4534G>A p.D1512N | Missense Mutation (SNP) | VAF 165/485 reads (34%) | SIFT tolerated (0.66); PolyPhen benign (0.18); catalogued as rs774441486, COSV51928553; ClinVar: uncertain significance / benign; called by muse, mutect2, varscan2
- UTP20 | c.7372G>A p.A2458T | Missense Mutation (SNP) | VAF 62/239 reads (26%) | SIFT tolerated (0.68); PolyPhen benign (0.014); catalogued as rs994190333; called by muse, mutect2, varscan2
- VCAN | c.2745A>C p.Q915H | Missense Mutation (SNP) | VAF 130/223 reads (58%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV54097337; called by muse, mutect2, varscan2
- ZNF175 | c.1208A>C p.N403T | Missense Mutation (SNP) | VAF 56/779 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as rs756933793; called by muse, mutect2
- ZNF324 | c.1432G>A p.E478K | Missense Mutation (SNP) | VAF 58/1310 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1373823644; called by muse, mutect2
- ZNF331 | c.182dup p.N61Kfs*4 | Frame Shift Ins (INS) | VAF 42/362 reads (12%) | catalogued as rs1476112027; called by mutect2, varscan2
- ZNF775 | c.1127G>A p.R376H | Missense Mutation (SNP) | VAF 239/835 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.493); catalogued as rs1179907707, COSV100301385; called by muse, mutect2, varscan2
- ABLIM3 | c.960G>T p.E320D | Missense Mutation (SNP) | VAF 158/310 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ACAN | c.4526T>A p.L1509H | Missense Mutation (SNP) | VAF 22/588 reads (4%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.999); called by muse, mutect2
- ACSM2A | c.1241T>C p.V414A (on ENST00000219054; = p.V335A on NM_001308169.2) | Missense Mutation (SNP) | VAF 24/440 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.615); called by muse, mutect2
- AFF3 | c.1109T>G p.L370R | Missense Mutation (SNP) | VAF 17/501 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ALDH1A3 | c.1520T>C p.L507P | Missense Mutation (SNP) | VAF 46/642 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ANKRD18B | c.642T>G p.S214R | Missense Mutation (SNP) | VAF 122/320 reads (38%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- ARHGAP31 | c.651C>A p.N217K | Missense Mutation (SNP) | VAF 39/220 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- ARL10 | c.34G>C p.A12P | Missense Mutation (SNP) | VAF 156/302 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.606); called by muse, mutect2
- ASTN1 | c.1484A>C p.K495T | Missense Mutation (SNP) | VAF 91/345 reads (26%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- BAHCC1 | c.1169G>T p.S390I | Missense Mutation (SNP) | VAF 82/1088 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.267); called by muse, mutect2
- BCKDHB | c.582_593del p.Y195_Q198del | In Frame Del (DEL) | VAF 99/446 reads (22%) | called by mutect2, pindel, varscan2
- BLZF1 | c.308G>A p.G103E | Missense Mutation (SNP) | VAF 136/434 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- BMP10 | c.238G>T p.D80Y | Missense Mutation (SNP) | VAF 142/569 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- CACNA1F | c.3903G>A p.M1301I | Missense Mutation (SNP) | VAF 22/199 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- CACNA1H | c.5839C>A p.P1947T | Missense Mutation (SNP) | VAF 207/681 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CCDC105 | c.410C>T p.A137V | Missense Mutation (SNP) | VAF 257/728 reads (35%) | SIFT tolerated (0.84); PolyPhen benign (0.35); called by muse, mutect2, varscan2
- CD101 | c.1231A>T p.R411* | Nonsense Mutation (SNP) | VAF 32/233 reads (14%) | called by muse, mutect2, varscan2
- CD163L1 | c.488C>T p.S163F | Missense Mutation (SNP) | VAF 78/629 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.596); called by muse, mutect2, varscan2
- CDC42BPA | c.4868A>G p.E1623G (on ENST00000334218 / NM_001366019.2; = p.E1610G on NM_003607.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/408 reads (11%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CGGBP1 | c.245A>C p.K82T | Missense Mutation (SNP) | VAF 150/462 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- CPE | c.928G>A p.V310I | Missense Mutation (SNP) | VAF 34/244 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CREB3L1 | c.1337A>T p.E446V | Missense Mutation (SNP) | VAF 175/651 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CRYBG3 | c.8166A>C p.E2722D | Missense Mutation (SNP) | VAF 44/344 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CTSA | c.1349T>C p.L450P | Missense Mutation (SNP) | VAF 91/445 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DBN1 | c.827T>C p.V276A | Missense Mutation (SNP) | VAF 148/321 reads (46%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- DNAH17 | c.7007A>C p.K2336T | Missense Mutation (SNP) | VAF 40/648 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2
- DNAH8 | c.12717T>G p.H4239Q | Missense Mutation (SNP) | VAF 88/337 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- DOCK5 | c.1379A>C p.K460T | Missense Mutation (SNP) | VAF 41/126 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- EFHD1 | c.52G>T p.E18* | Nonsense Mutation (SNP) | VAF 145/654 reads (22%) | called by muse, mutect2, varscan2
- EFNB3 | c.866A>G p.E289G | Missense Mutation (SNP) | VAF 222/685 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- EHBP1 | c.3575T>C p.L1192P | Missense Mutation (SNP) | VAF 42/490 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ERICH3 | c.3203C>T p.T1068I | Missense Mutation (SNP) | VAF 362/572 reads (63%) | SIFT deleterious (0.05); PolyPhen benign (0.056); called by muse, mutect2
- EXOC3 | c.844A>G p.I282V | Missense Mutation (SNP) | VAF 83/418 reads (20%) | SIFT tolerated (0.8); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- FAM149B1 | c.223A>T p.S75C | Missense Mutation (SNP) | VAF 114/358 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- FLG2 | c.5069A>G p.E1690G | Missense Mutation (SNP) | VAF 58/440 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FYB2 | c.772G>T p.V258F | Missense Mutation (SNP) | VAF 77/318 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- GAS8 | c.871A>T p.S291C | Missense Mutation (SNP) | VAF 177/534 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- HADHA | c.1498T>G p.F500V | Missense Mutation (SNP) | VAF 36/410 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2
- HES5 | c.265A>C p.S89R | Missense Mutation (SNP) | VAF 145/492 reads (29%) | SIFT tolerated (0.68); PolyPhen benign (0.066); called by mutect2, varscan2
- HOXA4 | c.413C>A p.P138H | Missense Mutation (SNP) | VAF 34/505 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.907); called by muse, mutect2
- IMMT | c.931A>T p.N311Y | Missense Mutation (SNP) | VAF 45/439 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.612); called by muse, mutect2, varscan2
- INTS8 | c.2037A>C p.Q679H | Missense Mutation (SNP) | VAF 35/452 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- IQCB1 | c.1529T>C p.L510P | Missense Mutation (SNP) | VAF 148/283 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ITFG2 | c.919C>T p.L307F | Missense Mutation (SNP) | VAF 46/677 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); called by muse, mutect2
- ITGAM | c.2246T>G p.L749R (on ENST00000648685 / NM_001145808.2; = p.L748R on NM_000632.4) | Missense Mutation (SNP) | VAF 104/383 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- IZUMO1 | c.482A>T p.K161M | Missense Mutation (SNP) | VAF 106/558 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- JMJD1C | c.4756T>G p.L1586V | Missense Mutation (SNP) | VAF 80/263 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KCNA4 | c.269C>A p.S90Y | Missense Mutation (SNP) | VAF 182/560 reads (33%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.039); called by muse, varscan2
- KCNN2 | c.209A>G p.K70R (on ENST00000264773; = p.K282R on NM_021614.4) | Missense Mutation (SNP) | VAF 155/346 reads (45%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.2); called by muse, mutect2, varscan2
- KIF26B | c.2878A>C p.S960R | Missense Mutation (SNP) | VAF 224/684 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- KRT13 | c.1226T>C p.L409P | Missense Mutation (SNP) | VAF 88/384 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAP3K8 | c.832A>T p.T278S | Missense Mutation (SNP) | VAF 33/244 reads (14%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- MAPKBP1 | c.4159C>G p.P1387A (on ENST00000456763 / NM_001128608.2; = p.P1381A on NM_014994.3) | Missense Mutation (SNP) | VAF 143/331 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- MEPCE | c.80G>A p.G27E | Missense Mutation (SNP) | VAF 396/739 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.483); called by muse, varscan2
- MTOR | c.1449C>G p.F483L | Missense Mutation (SNP) | VAF 115/405 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- MYH13 | c.2300T>A p.V767E | Missense Mutation (SNP) | VAF 32/352 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- MYO15A | c.701A>G p.E234G | Missense Mutation (SNP) | VAF 175/602 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NFKBIZ | c.2071_2072del p.H691Ffs*61 | Frame Shift Del (DEL) | VAF 90/295 reads (31%) | called by mutect2, pindel, varscan2
- NKX1-1 | c.848A>T p.K283M | Missense Mutation (SNP) | VAF 295/557 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NTM | c.934+7C>A | Splice Region (SNP) | VAF 107/348 reads (31%) | called by muse, mutect2, varscan2
- OR10G9 | c.274T>G p.S92A | Missense Mutation (SNP) | VAF 88/464 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- OR4N5 | c.320T>G p.L107R | Missense Mutation (SNP) | VAF 143/411 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- OTUD7A | c.2110A>T p.R704* (on ENST00000307050 / NM_001382637.1; = p.R697* on NM_130901.3) | Nonsense Mutation (SNP) | VAF 72/186 reads (39%) | called by muse, mutect2, varscan2
- PALM3 | c.716A>C p.E239A (on ENST00000340790; = p.E254A on NM_001145028.2) | Missense Mutation (SNP) | VAF 80/688 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- PARP6 | c.1708A>C p.I570L | Missense Mutation (SNP) | VAF 299/411 reads (73%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.768); called by muse, mutect2, varscan2
- PCDHB15 | c.1583A>G p.E528G | Missense Mutation (SNP) | VAF 255/578 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- PCDHB8 | c.2218G>A p.V740M | Missense Mutation (SNP) | VAF 159/340 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.084); called by muse, mutect2
- PCLO | c.14935G>C p.G4979R | Missense Mutation (SNP) | VAF 36/319 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PDIA6 | c.50C>T p.A17V | Missense Mutation (SNP) | VAF 67/464 reads (14%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- PLCB3 | c.1036T>G p.S346A | Missense Mutation (SNP) | VAF 133/470 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PTEN | c.725A>G p.E242G | Missense Mutation (SNP) | VAF 152/491 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.239); called by muse, mutect2, varscan2
- RSPH9 | c.550C>T p.L184F | Missense Mutation (SNP) | VAF 26/564 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2
- SCN10A | c.2921T>C p.L974P | Missense Mutation (SNP) | VAF 60/490 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SCN2A | c.3896T>G p.L1299R | Missense Mutation (SNP) | VAF 31/414 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SHISA6 | c.278C>T p.T93M | Missense Mutation (SNP) | VAF 399/619 reads (64%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- SLC26A3 | c.2035G>T p.V679L | Missense Mutation (SNP) | VAF 35/494 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); called by muse, mutect2
- SLC34A2 | c.1924A>G p.S642G | Missense Mutation (SNP) | VAF 208/424 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- SLC6A16 | c.226A>C p.T76P | Missense Mutation (SNP) | VAF 142/859 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- SOX11 | c.1126G>A p.A376T | Missense Mutation (SNP) | VAF 450/737 reads (61%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- STXBP5 | c.2227T>G p.F743V | Missense Mutation (SNP) | VAF 45/328 reads (14%) | SIFT tolerated (0.54); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- SUPT5H | c.1219G>T p.V407L | Missense Mutation (SNP) | VAF 84/560 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SYNE1 | c.19415T>A p.V6472E (on ENST00000367255 / NM_182961.4; = p.V6401E on NM_033071.3) | Missense Mutation (SNP) | VAF 117/342 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- SYT13 | c.1016A>G p.K339R | Missense Mutation (SNP) | VAF 46/392 reads (12%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- SYT5 | c.954A>C p.Q318H | Missense Mutation (SNP) | VAF 93/367 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- TFEC | c.713T>G p.L238R | Missense Mutation (SNP) | VAF 49/452 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- TIAM1 | c.2549A>G p.K850R | Missense Mutation (SNP) | VAF 74/275 reads (27%) | SIFT tolerated (0.54); PolyPhen benign (0.042); called by muse, mutect2
- TMEM200C | c.1630G>A p.G544S | Missense Mutation (SNP) | VAF 193/606 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.492); called by muse, varscan2
- TP53INP1 | c.404A>G p.H135R | Missense Mutation (SNP) | VAF 202/393 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRAPPC9 | c.200A>C p.E67A | Missense Mutation (SNP) | VAF 19/592 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.591); called by muse, mutect2
- TSC22D1 | c.2347A>C p.S783R | Missense Mutation (SNP) | VAF 11/268 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2
- UROC1 | c.994A>G p.T332A | Missense Mutation (SNP) | VAF 125/285 reads (44%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- VAC14 | c.1027A>G p.R343G | Missense Mutation (SNP) | VAF 174/587 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- VPS50 | c.752A>C p.N251T | Missense Mutation (SNP) | VAF 35/227 reads (15%) | SIFT tolerated (0.64); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZC3H6 | c.1715G>T p.G572V | Missense Mutation (SNP) | VAF 128/610 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.647); called by muse, mutect2, varscan2
- ZDBF2 | c.3489T>G p.D1163E | Missense Mutation (SNP) | VAF 116/443 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- ZDBF2 | c.6148T>A p.F2050I | Missense Mutation (SNP) | VAF 17/437 reads (4%) | SIFT tolerated (0.26); PolyPhen benign (0.014); called by muse, mutect2
- ZFHX3 | c.5548T>A p.L1850M | Missense Mutation (SNP) | VAF 74/476 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- ZFP36L1 | c.202dup p.L68Pfs*7 | Frame Shift Ins (INS) | VAF 139/502 reads (28%) | called by mutect2, pindel, varscan2
- ZNF169 | c.662T>C p.L221P | Missense Mutation (SNP) | VAF 111/210 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF250 | c.263C>T p.A88V | Missense Mutation (SNP) | VAF 48/421 reads (11%) | SIFT tolerated (0.54); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ZNF285 | c.1667T>C p.L556P | Missense Mutation (SNP) | VAF 24/488 reads (5%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.995); called by muse, mutect2
- ZNF43 | c.1959A>C p.E653D | Missense Mutation (SNP) | VAF 136/403 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- ZNF484 | c.2356A>G p.T786A | Missense Mutation (SNP) | VAF 257/257 reads (100%) | SIFT tolerated (0.07); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- ZNF675 | c.908A>C p.K303T | Missense Mutation (SNP) | VAF 102/281 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ALG8 | c.966G>A p.Q322= | Silent (SNP) | VAF 149/461 reads (32%) | called by muse, mutect2, varscan2
- BNC1 | c.714C>T p.S238= | Silent (SNP) | VAF 160/659 reads (24%) | called by muse, mutect2, varscan2
- CAPN15 | c.1677G>A p.A559= | Silent (SNP) | VAF 172/482 reads (36%) | catalogued as rs1176553372; called by muse, mutect2, varscan2
- CD163L1 | c.489C>G p.S163= | Silent (SNP) | VAF 79/634 reads (12%) | called by muse, mutect2, varscan2
- CDHR2 | c.3198G>A p.A1066= | Silent (SNP) | VAF 119/275 reads (43%) | catalogued as COSV56134609; called by muse, mutect2, varscan2
- CNTN6 | c.1356A>G p.Q452= | Silent (SNP) | VAF 81/258 reads (31%) | called by muse, mutect2, varscan2
- DEFB110 | c.91T>C p.L31= | Silent (SNP) | VAF 68/513 reads (13%) | catalogued as COSV64484853; called by muse, mutect2, varscan2
- GLI3 | c.3390C>T p.D1130= | Silent (SNP) | VAF 478/480 reads (100%) | catalogued as rs756608797, COSV67885638; called by muse, mutect2, varscan2
- GOLGA6A | c.201G>C p.G67= | Silent (SNP) | VAF 76/1831 reads (4%) | catalogued as COSV51805966; called by muse, mutect2
- HASPIN | c.1834T>C p.L612= | Silent (SNP) | VAF 25/416 reads (6%) | called by muse, mutect2
- HCFC2 | c.135C>A p.I45= | Silent (SNP) | VAF 130/396 reads (33%) | catalogued as COSV57559826; called by muse, varscan2
- HDAC4 | c.1644G>A p.K548= | Silent (SNP) | VAF 62/1044 reads (6%) | called by muse, mutect2
- IGKV1D-17 | c.246A>T p.S82= | Silent (SNP) | VAF 150/982 reads (15%) | called by muse, varscan2
- IRF6 | c.585T>G p.T195= | Silent (SNP) | VAF 182/560 reads (33%) | called by muse, mutect2, varscan2
- JUP | c.2193C>T p.D731= | Silent (SNP) | VAF 645/827 reads (78%) | catalogued as rs199683273; called by muse, mutect2, varscan2
- KCNC2 | c.429C>T p.I143= | Silent (SNP) | VAF 222/467 reads (48%) | catalogued as COSV54365833; called by muse, mutect2, varscan2
- KIAA2012 | c.1563C>T p.G521= | Silent (SNP) | VAF 130/537 reads (24%) | catalogued as rs773357509; called by muse, mutect2, varscan2
- KIF3B | c.537G>A p.L179= | Silent (SNP) | VAF 110/749 reads (15%) | called by muse, mutect2, varscan2
- KLRC2 | c.558A>C p.T186= | Silent (SNP) | VAF 90/375 reads (24%) | catalogued as rs1189724853; called by muse, mutect2, varscan2
- MARCHF4 | c.1134T>G p.A378= | Silent (SNP) | VAF 132/458 reads (29%) | called by mutect2, varscan2
- MEIOC | c.1401T>A p.S467= | Silent (SNP) | VAF 17/568 reads (3%) | called by muse, mutect2
- MGAM | c.3240T>A p.G1080= | Silent (SNP) | VAF 183/685 reads (27%) | called by muse, mutect2, varscan2
- MYO1E | c.1632T>C p.S544= | Silent (SNP) | VAF 28/495 reads (6%) | called by muse, mutect2
- NRG3 | c.906C>T p.G302= | Silent (SNP) | VAF 255/396 reads (64%) | catalogued as COSV64564815, COSV64584431; called by muse, mutect2, varscan2
- NYAP2 | c.666G>A p.L222= | Silent (SNP) | VAF 336/637 reads (53%) | called by muse, mutect2, varscan2
- OR4Q3 | c.33A>G p.K11= | Silent (SNP) | VAF 28/760 reads (4%) | called by muse, mutect2
- OTUD7A | c.2109C>T p.R703= (on ENST00000307050 / NM_001382637.1; = p.R696= on NM_130901.3) | Silent (SNP) | VAF 72/186 reads (39%) | called by muse, mutect2, varscan2
- PSD | c.2433G>A p.T811= | Silent (SNP) | VAF 130/471 reads (28%) | catalogued as rs569894593, COSV99193888; called by muse, mutect2, varscan2
- PSG1 | c.348C>T p.D116= | Silent (SNP) | VAF 260/677 reads (38%) | catalogued as rs137928256, COSV99740008; called by muse, mutect2, varscan2
- RALGAPA1 | c.1933T>C p.L645= | Silent (SNP) | VAF 42/390 reads (11%) | called by muse, mutect2, varscan2
- SBF2 | c.1011T>A p.A337= | Silent (SNP) | VAF 119/339 reads (35%) | called by muse, mutect2, varscan2
- SMAD6 | c.1368C>T p.D456= | Silent (SNP) | VAF 485/680 reads (71%) | called by muse, mutect2, varscan2
- SNRK | c.2034A>G p.K678= | Silent (SNP) | VAF 141/483 reads (29%) | called by muse, mutect2, varscan2
- STXBP5 | c.1941C>T p.G647= | Silent (SNP) | VAF 96/322 reads (30%) | called by muse, varscan2
- SUGP1 | c.348A>G p.T116= | Silent (SNP) | VAF 160/490 reads (33%) | catalogued as rs1432544613; called by muse, mutect2, varscan2
- TDRD9 | c.1833A>C p.I611= | Silent (SNP) | VAF 152/431 reads (35%) | called by muse, mutect2, varscan2
- TMEM132C | c.1239A>T p.T413= | Silent (SNP) | VAF 57/579 reads (10%) | called by muse, mutect2, varscan2
- TRIM72 | c.1023C>T p.S341= | Silent (SNP) | VAF 272/807 reads (34%) | catalogued as rs756750610, COSV59068668; called by muse, mutect2, varscan2
- TRIP12 | c.5193T>G p.T1731= | Silent (SNP) | VAF 122/415 reads (29%) | called by muse, mutect2, varscan2
- TRPV3 | c.1872C>T p.S624= | Silent (SNP) | VAF 26/518 reads (5%) | called by muse, mutect2
- TTN | c.96186A>G p.R32062= (on ENST00000591111; = p.R24638= on NM_003319.4) | Silent (SNP) | VAF 47/432 reads (11%) | catalogued as rs750240807; called by muse, mutect2, varscan2
- ZC3H12A | c.471C>T p.C157= | Silent (SNP) | VAF 122/415 reads (29%) | called by muse, mutect2, varscan2
- ZNF200 | c.730C>A p.R244= | Silent (SNP) | VAF 137/423 reads (32%) | catalogued as COSV67724291; called by muse, mutect2, varscan2
- ZNF679 | c.273T>G p.S91= | Silent (SNP) | VAF 58/208 reads (28%) | called by muse, mutect2, varscan2
- ZNF8 | c.1170T>C p.T390= | Silent (SNP) | VAF 78/687 reads (11%) | called by muse, mutect2, varscan2
- CCNQ | chrX:153599408 T>C | 5'Flank (SNP) | VAF 45/193 reads (23%) | called by muse, mutect2, varscan2
- COL6A5 | c.-79T>A | 5'UTR (SNP) | VAF 148/308 reads (48%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1514+5896T>A | Intron (SNP) | VAF 268/415 reads (65%) | called by muse, mutect2, varscan2
- NRG3 | c.824-191979G>A | Intron (SNP) | VAF 167/277 reads (60%) | called by muse, mutect2, varscan2
- PKM | c.-13-2080A>C | Intron (SNP) | VAF 34/678 reads (5%) | called by muse, mutect2
- SLITRK2 | chrX:145827765 T>C | 3'Flank (SNP) | VAF 88/88 reads (100%) | called by muse, mutect2, varscan2
- TJP1 | c.*1_*13del | 3'UTR (DEL) | VAF 93/166 reads (56%) | called by mutect2, pindel, varscan2
